Somatic mutation profile of tumor specimen 0DVM1N from CCDI case PBCMVF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neuroepithelioma, NOS; Tissue or organ of origin: Occipital lobe; Age at diagnosis: 17.2 years (6,298 days).
Specimen 0DVM1N: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 49a195d8-a89d-4aa8-af49-96ba5b1e90b8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVM1R (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7fb09c27-888e-4611-a765-24566b948c7d

The open-access MAF lists 16 somatic variants for this specimen: 12 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, 3'UTR 2, Splice Site 1, Silent 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDS2 | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 159/428 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.773); catalogued as rs146586086; called by muse, mutect2, varscan2
- FLT4 | c.2180C>T p.A727V | Missense Mutation (SNP) | VAF 15/257 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.047); catalogued as rs762560832, COSV56110531; called by muse, mutect2
- OR9Q2 | c.581C>T p.T194I | Missense Mutation (SNP) | VAF 323/873 reads (37%) | SIFT tolerated (0.99); PolyPhen benign (0.017); catalogued as rs771087731; called by muse, mutect2, varscan2
- SCO2 | c.727C>T p.R243W | Missense Mutation (SNP) | VAF 54/432 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs760717208, COSV99329750; called by muse, varscan2
- SHCBP1L | c.1710+1G>A p.X570_splice | Splice Site (SNP) | VAF 68/702 reads (10%) | catalogued as rs375280566; called by muse, mutect2
- ZNF804B | c.1658A>G p.N553S | Missense Mutation (SNP) | VAF 431/1084 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as rs1562743888; called by muse, mutect2, varscan2
- ATP7B | c.1931A>G p.K644R | Missense Mutation (SNP) | VAF 436/1220 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- BBX | c.2771G>T p.G924V (on ENST00000325805 / NM_001142568.3; = p.G894V on NM_020235.7) | Missense Mutation (SNP) | VAF 201/850 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- IFI30 | c.250T>G p.F84V | Missense Mutation (SNP) | VAF 199/520 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MAP7 | c.1415G>A p.G472D | Missense Mutation (SNP) | VAF 84/817 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MEIS1 | c.334T>G p.C112G | Missense Mutation (SNP) | VAF 80/910 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- ZSCAN26 | c.619G>A p.E207K (on ENST00000623276 / NM_001111039.2; = p.E73K on NM_152736.5) | Missense Mutation (SNP) | VAF 60/929 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2
- TFR2 | c.249C>T p.P83= | Silent (SNP) | VAF 21/552 reads (4%) | catalogued as COSV50517470; called by muse, mutect2
- CSPP1 | c.*80T>C | 3'UTR (SNP) | VAF 22/168 reads (13%) | called by muse, mutect2, varscan2
- SERF2 | c.7+16C>A | Intron (SNP) | VAF 50/157 reads (32%) | called by muse, mutect2, varscan2
- ZNF547 | c.*98T>G | 3'UTR (SNP) | VAF 93/261 reads (36%) | called by muse, mutect2, varscan2
